Somatic mutation profile of tumor specimen TCGA-DJ-A3VE-01A (aliquot TCGA-DJ-A3VE-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 50.4 years (18,417 days).
Specimen TCGA-DJ-A3VE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eeb7b7ac-3043-40dc-bee9-07ff391ad97d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VE-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VE-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c5d8024-35b9-4bf1-b5ba-fd401b3a8ca2

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APOL2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs747089040, COSV50772418; called by muse, mutect2, varscan2
- BMP6 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs1232632844, COSV51663214; called by muse, mutect2
- DERL1 | c.437T>C p.F146S | Missense Mutation (SNP) | VAF 90/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52365368; called by muse, mutect2, varscan2
- DHX36 | c.353C>G p.A118G | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV57674679; called by muse, mutect2, varscan2
- GZF1 | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV57636953; called by muse, mutect2, varscan2
- VPS4B | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 121/328 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs774790929, COSV53070069; called by muse, mutect2, varscan2
- CACNA1B | c.513C>T p.F171= | Silent (SNP) | VAF 19/251 reads (8%) | catalogued as rs200076426, COSV53119912; called by muse, mutect2
- COL12A1 | c.2478G>A p.T826= | Silent (SNP) | VAF 15/139 reads (11%) | catalogued as rs781557444, COSV100486450, COSV59400620; called by muse, mutect2, varscan2
- PGAP4 | c.1161C>T p.H387= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV66388032; called by muse, mutect2, varscan2
